Somatic mutation profile of tumor specimen 0DP0N5 from CCDI case PBCDBM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Middle ear; Age at diagnosis: 1.7 years (613 days).
Specimen 0DP0N5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2cfc88f-06f5-4f9a-b47f-a45c126af8e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP0MT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf2485f-e9be-4f5d-94d5-91a60865e5d6

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 3, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 182/594 reads (31%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 1009/2258 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LMAN2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 348/1181 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs761995183, COSV57424489; called by muse, mutect2, varscan2
- MGAM | c.1637C>A p.T546K | Missense Mutation (SNP) | VAF 232/882 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV72076070; called by mutect2, varscan2
- MYOM2 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 229/1072 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs373951587; called by muse, mutect2, varscan2
- SLITRK3 | c.978C>A p.Y326* | Nonsense Mutation (SNP) | VAF 362/1234 reads (29%) | catalogued as COSV99579630; called by mutect2, varscan2
- SSC5D | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 102/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs558923564; called by muse, mutect2, varscan2
- TACR1 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 350/1126 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs150873497, COSV59486486; called by muse, mutect2, varscan2
- CACNA1A | c.2111C>T p.T704I | Missense Mutation (SNP) | VAF 61/827 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC168 | c.12754G>T p.E4252* | Nonsense Mutation (SNP) | VAF 351/1985 reads (18%) | called by muse, mutect2, varscan2
- DMXL1 | c.8527G>A p.D2843N | Missense Mutation (SNP) | VAF 247/938 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HES1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 207/699 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- OR4C6 | c.724C>A p.L242I | Missense Mutation (SNP) | VAF 320/1130 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.05); called by mutect2, varscan2
- TGFBI | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 355/1146 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRIM42 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USF3 | c.4693C>A p.Q1565K | Missense Mutation (SNP) | VAF 348/1240 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AASS | c.-55G>T | 5'UTR (SNP) | VAF 109/348 reads (31%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.861+54G>T | Intron (SNP) | VAF 99/751 reads (13%) | called by muse, mutect2, varscan2
